Somatic mutation profile of tumor specimen MMRF_2822_1_BM_CD138pos (aliquot MMRF_2822_1_BM_CD138pos_T1_KHS5U_L15708) from MMRF case MMRF_2822, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 58.4 years (21,325 days).
Specimen MMRF_2822_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9a1d47f7-2ca6-4caf-a033-86f9e641a83d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2822_1_PB_WBC (Blood Derived Normal), aliquot MMRF_2822_1_PB_WBC_C3_KHS5U_L15754; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4c4f7c11-f363-4567-8b3a-31eabc57b4f0

The open-access MAF lists 117 somatic variants for this specimen: 50 protein-altering or splice-affecting, 14 silent, 53 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, 3'UTR 26, Intron 16, Silent 14, 5'UTR 6, Frame Shift Ins 3, Nonsense Mutation 3, Splice Site 3, RNA 3, Frame Shift Del 2, 3'Flank 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.182A>G p.Q61R | Missense Mutation (SNP) | VAF 19/154 reads (12%) | hotspot (GDC flag); SIFT tolerated (0.06); PolyPhen benign (0.251); catalogued as rs11554290, COSV54736340, COSV54736624, COSV54738969, COSV54747786; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- NRAS | c.37G>C p.G13R | Missense Mutation (SNP) | VAF 32/500 reads (6%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs121434595, COSV54736386, COSV54736476, COSV54736550; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2
- RD3 | c.112C>T p.R38* | Nonsense Mutation (SNP) | VAF 15/137 reads (11%) | catalogued as rs786205148, CM130361, COSV65362080; ClinVar: pathogenic; called by muse, mutect2
- ALDH16A1 | c.703C>T p.P235S | Missense Mutation (SNP) | VAF 41/174 reads (24%) | SIFT tolerated (0.52); PolyPhen benign (0.138); catalogued as rs1414675437, COSV53192614; called by muse, mutect2, varscan2
- ANKS1A | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 4/24 reads (17%) | SIFT tolerated, low confidence (0.37); PolyPhen benign (0.005); catalogued as rs1354655055, COSV63543043; called by mutect2, varscan2
- ATF6B | c.1892C>T p.S631L | Missense Mutation (SNP) | VAF 56/133 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.37); catalogued as COSV64352313; called by muse, mutect2, varscan2
- CDRT4 | c.358C>A p.H120N | Missense Mutation (SNP) | VAF 152/406 reads (37%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs756426503; called by muse, mutect2
- CLU | c.679C>T p.R227C | Missense Mutation (SNP) | VAF 59/178 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs769830551, COSV57066921; called by muse, mutect2, varscan2
- DACH2 | c.1537A>C p.T513P | Missense Mutation (SNP) | VAF 22/33 reads (67%) | SIFT deleterious (0.01); PolyPhen benign (0.038); catalogued as COSV64166639; called by muse, mutect2, varscan2
- DDX5 | c.440_441+2del p.X147_splice | Splice Site (DEL) | VAF 26/290 reads (9%) | catalogued as rs782442161; called by mutect2, pindel
- DNAH6 | c.7469A>G p.Y2490C | Missense Mutation (SNP) | VAF 9/167 reads (5%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.495); catalogued as rs1239414707; called by muse, mutect2
- KCNJ1 | c.931C>T p.R311W | Missense Mutation (SNP) | VAF 51/187 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs779747435, CM994547, COSV60661865, COSV60662273; called by muse, mutect2, varscan2
- KCNJ15 | c.83G>A p.R28H | Missense Mutation (SNP) | VAF 253/323 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376443264; called by muse, mutect2, varscan2
- KRT85 | c.220G>A p.G74S | Missense Mutation (SNP) | VAF 19/49 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.026); catalogued as rs746139185, COSV57737734; called by muse, mutect2, varscan2
- MELK | c.1318_1319del p.M440Vfs*3 | Frame Shift Del (DEL) | VAF 22/134 reads (16%) | catalogued as rs778108102; called by mutect2, pindel, varscan2
- PASD1 | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 22/210 reads (10%) | SIFT tolerated (0.57); PolyPhen benign (0.094); catalogued as COSV64858460; called by muse, mutect2, varscan2
- POM121L2 | c.881G>A p.R294Q | Missense Mutation (SNP) | VAF 38/102 reads (37%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs532787152; called by muse, mutect2, varscan2
- PTGIS | c.1229T>G p.L410R | Missense Mutation (SNP) | VAF 13/125 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs749377505; called by muse, mutect2, varscan2
- RNF151 | c.520C>T p.R174C | Missense Mutation (SNP) | VAF 63/140 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.732); catalogued as rs376089444; called by muse, mutect2, varscan2
- SAMD9 | c.1651G>A p.D551N | Missense Mutation (SNP) | VAF 26/183 reads (14%) | SIFT tolerated (0.17); PolyPhen benign (0.024); catalogued as COSV66075095; called by muse, mutect2
- SULT1E1 | c.385C>T p.R129W | Missense Mutation (SNP) | VAF 48/185 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs762229711; called by muse, mutect2, varscan2
- TTLL3 | c.814C>T p.R272C | Missense Mutation (SNP) | VAF 32/94 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs367876442; called by muse, mutect2, varscan2
- ZNF674 | c.239G>A p.G80D | Missense Mutation (SNP) | VAF 33/46 reads (72%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs748555255; called by muse, mutect2, varscan2
- ANAPC2 | c.179A>T p.E60V | Missense Mutation (SNP) | VAF 11/166 reads (7%) | SIFT tolerated (0.07); PolyPhen benign (0.298); called by muse, mutect2
- ANKAR | c.670A>G p.T224A | Missense Mutation (SNP) | VAF 103/295 reads (35%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.723); called by muse, mutect2, varscan2
- C18orf21 | c.20T>C p.L7P | Missense Mutation (SNP) | VAF 18/47 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); called by muse, mutect2, varscan2
- CCT8L2 | c.1190A>T p.D397V | Missense Mutation (SNP) | VAF 39/127 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); called by muse, mutect2, varscan2
- DYNC2H1 | c.11448C>A p.N3816K | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2
- FAM193A | c.2526_2527insAC p.V843Tfs*14 | Frame Shift Ins (INS) | VAF 83/156 reads (53%) | called by mutect2, varscan2*
- FAM193A | c.2527_2528insACTCCCCT p.V843Dfs*16 | Frame Shift Ins (INS) | VAF 88/163 reads (54%) | called by mutect2, pindel*, varscan2*
- FAT1 | c.9764C>T p.A3255V | Missense Mutation (SNP) | VAF 64/293 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.059); called by muse, mutect2, varscan2
- FSIP2 | c.6350C>G p.T2117S | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.497); called by muse, mutect2, varscan2
- HECW1 | c.4754C>A p.S1585* | Nonsense Mutation (SNP) | VAF 64/286 reads (22%) | called by muse, mutect2, varscan2
- ITPR1 | c.295G>A p.E99K | Missense Mutation (SNP) | VAF 10/232 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- IWS1 | c.1725_1728del p.R575Sfs*2 | Frame Shift Del (DEL) | VAF 11/49 reads (22%) | called by pindel, varscan2
- LRRC66 | c.79A>C p.K27Q | Missense Mutation (SNP) | VAF 16/172 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.536); called by muse, mutect2
- LYST | c.9925+1G>A p.X3309_splice | Splice Site (SNP) | VAF 6/74 reads (8%) | called by muse, mutect2
- MEGF6 | c.2838C>A p.A946= | Splice Region (SNP) | VAF 36/133 reads (27%) | called by muse, mutect2, varscan2
- MRPL48 | c.161A>T p.H54L | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.747); called by muse, mutect2, varscan2
- MUC17 | c.3989C>T p.S1330L | Missense Mutation (SNP) | VAF 63/692 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.307); called by muse, mutect2
- NUFIP2 | c.504T>G p.Y168* | Nonsense Mutation (SNP) | VAF 12/130 reads (9%) | called by muse, mutect2
- PCDHA12 | c.1126G>T p.D376Y | Missense Mutation (SNP) | VAF 14/226 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); called by muse, mutect2
- PSAP | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 25/83 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.827); called by muse, mutect2, varscan2
- RNF31 | c.2404-2A>G p.X802_splice | Splice Site (SNP) | VAF 28/119 reads (24%) | called by muse, mutect2, varscan2
- RTEL1 | c.3514G>C p.E1172Q | Missense Mutation (SNP) | VAF 22/244 reads (9%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.006); called by muse, mutect2
- SCIMP | c.417T>G p.N139K | Missense Mutation (SNP) | VAF 34/86 reads (40%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, varscan2
- SLC35B1 | c.1039G>C p.D347H (on ENST00000649906; = p.D310H on NM_005827.4) | Missense Mutation (SNP) | VAF 41/378 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TSC2 | c.764C>A p.P255H | Missense Mutation (SNP) | VAF 8/118 reads (7%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); called by muse, mutect2
- TXNIP | c.900_904dup p.L302Qfs*3 | Frame Shift Ins (INS) | VAF 40/192 reads (21%) | called by mutect2, varscan2
- ZNF606 | c.977T>G p.F326C | Missense Mutation (SNP) | VAF 32/149 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- B3GALNT1 | c.66C>G p.L22= | Silent (SNP) | VAF 41/207 reads (20%) | called by muse, mutect2, varscan2
- CD83 | c.126G>A p.Q42= | Silent (SNP) | VAF 80/165 reads (48%) | catalogued as COSV100997704, COSV64786786; called by muse, mutect2, varscan2
- CFAP92 | c.1890C>T p.S630= | Silent (SNP) | VAF 13/132 reads (10%) | called by muse, mutect2, varscan2
- CNTN5 | c.1674T>G p.G558= | Silent (SNP) | VAF 64/382 reads (17%) | catalogued as COSV99682319; called by muse, mutect2, varscan2
- HERC1 | c.5220G>T p.L1740= | Silent (SNP) | VAF 33/266 reads (12%) | called by muse, mutect2, varscan2
- KANK4 | c.939G>A p.P313= | Silent (SNP) | VAF 35/157 reads (22%) | catalogued as rs559482425; called by muse, mutect2, varscan2
- OGG1 | c.87T>C p.P29= | Silent (SNP) | VAF 58/186 reads (31%) | called by muse, mutect2, varscan2
- OR8D4 | c.729C>T p.S243= | Silent (SNP) | VAF 20/406 reads (5%) | catalogued as COSV58431286; called by muse, mutect2
- OVOL3 | c.144C>T p.V48= | Silent (SNP) | VAF 15/262 reads (6%) | called by muse, mutect2
- SPATA9 | c.300A>G p.R100= | Silent (SNP) | VAF 69/448 reads (15%) | called by muse, mutect2, varscan2
- SPHKAP | c.3663C>T p.A1221= | Silent (SNP) | VAF 50/119 reads (42%) | called by muse, mutect2, varscan2
- ST8SIA4 | c.276A>G p.E92= | Silent (SNP) | VAF 96/316 reads (30%) | called by muse, mutect2, varscan2
- TUBE1 | c.1341A>G p.L447= | Silent (SNP) | VAF 71/206 reads (34%) | catalogued as rs781864721; called by muse, mutect2, varscan2
- UMODL1 | c.285G>A p.E95= | Silent (SNP) | VAF 14/172 reads (8%) | called by muse, mutect2
- ADGB | c.3862+1456A>G | Intron (SNP) | VAF 39/137 reads (28%) | called by muse, mutect2, varscan2
- ADGRG5 | n.322G>A | RNA (SNP) | VAF 32/152 reads (21%) | called by muse, varscan2
- AIFM2 | c.*1845G>A | 3'UTR (SNP) | VAF 10/100 reads (10%) | catalogued as rs1173897190, COSV57160461; called by muse, varscan2
- AMD1 | c.*1198G>A | 3'UTR (SNP) | VAF 4/73 reads (5%) | catalogued as rs1338067926; called by muse, mutect2
- BEND3 | c.*1453T>C | 3'UTR (SNP) | VAF 25/79 reads (32%) | called by muse, mutect2, varscan2
- CADPS | c.1325+19761G>A | Intron (SNP) | VAF 12/52 reads (23%) | catalogued as rs1008524224; called by muse, mutect2, varscan2
- CCDC144A | c.4098+495T>C | Intron (SNP) | VAF 52/230 reads (23%) | catalogued as rs1403319180; called by muse, mutect2, varscan2
- CHMP2B | c.425-50T>C | Intron (SNP) | VAF 67/180 reads (37%) | called by muse, mutect2, varscan2
- DACH1 | chr13:71439941 A>C | 3'Flank (SNP) | VAF 21/60 reads (35%) | called by muse, mutect2, varscan2
- DMTF1 | c.*757T>C | 3'UTR (SNP) | VAF 7/98 reads (7%) | catalogued as rs1268243386; called by muse, mutect2
- DSC1 | c.-35C>G | 5'UTR (SNP) | VAF 6/44 reads (14%) | catalogued as COSV57146033; called by muse, mutect2, varscan2
- DSCR4 | n.471A>C | RNA (SNP) | VAF 47/65 reads (72%) | called by muse, mutect2, varscan2
- EIF1AY | c.*714A>C | 3'UTR (SNP) | VAF 23/31 reads (74%) | called by muse, mutect2, varscan2
- F13A1 | c.1113-9164G>A | Intron (SNP) | VAF 114/581 reads (20%) | called by muse, mutect2, varscan2
- F9 | c.*91T>G | 3'UTR (SNP) | VAF 140/160 reads (88%) | called by muse, varscan2
- F9 | c.*174T>G | 3'UTR (SNP) | VAF 86/100 reads (86%) | catalogued as rs770172170; called by muse, varscan2
- FMNL3 | c.*7953T>C | 3'UTR (SNP) | VAF 18/40 reads (45%) | called by muse, varscan2
- FMNL3 | c.*7880T>C | 3'UTR (SNP) | VAF 12/26 reads (46%) | called by muse, varscan2
- GADL1 | c.1250+1706T>A | Intron (SNP) | VAF 6/35 reads (17%) | called by mutect2, varscan2
- GTF3C1 | c.*14G>A | 3'UTR (SNP) | VAF 12/20 reads (60%) | catalogued as rs748974022, COSV100649600; called by muse, varscan2
- INSRR | c.*491G>A | 3'UTR (SNP) | VAF 20/147 reads (14%) | called by muse, mutect2, varscan2
- LRRC4C | c.*145T>C | 3'UTR (SNP) | VAF 21/79 reads (27%) | catalogued as rs1055691012; called by muse, mutect2, varscan2
- MAP2K1 | c.-313G>A | 5'UTR (SNP) | VAF 10/180 reads (6%) | called by muse, mutect2
- MFAP3L | c.*1170T>G | 3'UTR (SNP) | VAF 47/155 reads (30%) | called by muse, mutect2, varscan2
- MTDH | c.*3579_*3583del | 3'UTR (DEL) | VAF 20/63 reads (32%) | catalogued as rs781634871; called by mutect2, pindel, varscan2
- NAA80 | c.*48G>A | 3'UTR (SNP) | VAF 34/73 reads (47%) | catalogued as rs990717436; called by muse, mutect2, varscan2
- NOSIP | c.725+18G>A | Intron (SNP) | VAF 32/284 reads (11%) | called by muse, mutect2, varscan2
- NUAK1 | c.*375G>C | 3'UTR (SNP) | VAF 55/165 reads (33%) | called by muse, mutect2, varscan2
- OSBPL11 | c.-218T>G | 5'UTR (SNP) | VAF 31/65 reads (48%) | called by muse, mutect2, varscan2
- OSBPL11 | c.-335T>A | 5'UTR (SNP) | VAF 21/43 reads (49%) | called by muse, mutect2, varscan2
- PAQR3 | c.*6-664C>T | Intron (SNP) | VAF 58/207 reads (28%) | catalogued as rs1026375665; called by muse, mutect2, varscan2
- PCDH12 | c.-279T>C | 5'UTR (SNP) | VAF 54/187 reads (29%) | called by muse, mutect2, varscan2
- PCOLCE | c.463+254G>T | Intron (SNP) | VAF 5/62 reads (8%) | called by muse, mutect2
- PDCD2 | c.658+376G>A | Intron (SNP) | VAF 12/34 reads (35%) | called by muse, mutect2, varscan2
- PNMA2 | c.*1425T>C | 3'UTR (SNP) | VAF 23/67 reads (34%) | catalogued as rs1403771246; called by muse, mutect2, varscan2
- POU2F3 | c.*1456T>G | 3'UTR (SNP) | VAF 34/68 reads (50%) | called by muse, mutect2, varscan2
- PPFIBP1 | c.1633+18G>A | Intron (SNP) | VAF 6/79 reads (8%) | called by muse, mutect2
- PPP1R9A | c.*1705T>C | 3'UTR (SNP) | VAF 41/156 reads (26%) | called by muse, mutect2, varscan2
- RNH1 | c.-87-343G>A | Intron (SNP) | VAF 10/238 reads (4%) | called by muse, mutect2
- SCIMP | c.*83T>A | 3'UTR (SNP) | VAF 14/36 reads (39%) | called by muse, varscan2
- SEC14L1 | c.-240+247A>C | Intron (SNP) | VAF 44/198 reads (22%) | called by muse, mutect2, varscan2
- SEMA5A | c.*6553A>C | 3'UTR (SNP) | VAF 8/105 reads (8%) | called by muse, mutect2
- SLC22A18AS | c.-11G>A | 5'UTR (SNP) | VAF 28/438 reads (6%) | called by muse, mutect2
- SLC35B1 | c.*381G>A | 3'UTR (SNP) | VAF 27/235 reads (11%) | catalogued as rs968221948, COSV53604448; called by muse, mutect2, varscan2
- SLC35B1 | c.*285G>C | 3'UTR (SNP) | VAF 13/185 reads (7%) | called by muse, mutect2
- SLC35B1 | c.766+103A>T | Intron (SNP) | VAF 55/434 reads (13%) | called by muse, mutect2, varscan2
- TBX2 | chr17:61412339 G>A | 3'Flank (SNP) | VAF 38/466 reads (8%) | catalogued as rs754159218; called by muse, mutect2
- TMEM200A | c.*1075A>G | 3'UTR (SNP) | VAF 14/59 reads (24%) | called by muse, mutect2, varscan2
- TPRXL | n.638G>A | RNA (SNP) | VAF 25/140 reads (18%) | catalogued as rs749530804; called by muse, mutect2, varscan2
- TTC7B | c.1967-155_1967-152dup | Intron (INS) | VAF 9/26 reads (35%) | called by mutect2, pindel, varscan2
- UNC5B | c.*2181G>A | 3'UTR (SNP) | VAF 44/135 reads (33%) | catalogued as rs1053469223; called by muse, mutect2, varscan2
- UROS | c.394+4467A>T | Intron (SNP) | VAF 139/365 reads (38%) | called by muse, mutect2, varscan2
- WDR72 | c.*3046A>C | 3'UTR (SNP) | VAF 38/92 reads (41%) | called by muse, mutect2, varscan2
